Somatic mutation profile of tumor specimen TCGA-D1-A16V-01A (aliquot TCGA-D1-A16V-01A-11D-A12J-09) from TCGA case TCGA-D1-A16V, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 78.4 years (28,635 days).
Specimen TCGA-D1-A16V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2bef04f9-0c96-4064-8f43-68a4ecec17f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A16V-10A (Blood Derived Normal), aliquot TCGA-D1-A16V-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a1d61f4-7ba1-472c-8973-7951ba757bf9

The open-access MAF lists 47 somatic variants for this specimen: 38 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 8, Nonsense Mutation 4, Frame Shift Del 2, Splice Site 2, In Frame Ins 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 156/365 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1348_1353dup p.H450_E451dup (on ENST00000521381 / NM_181523.3; = p.H180_E181dup on NM_181504.4) | In Frame Ins (INS) | VAF 103/283 reads (36%) | hotspot (GDC flag); called by mutect2, varscan2
- PTEN | c.518G>T p.R173L | Missense Mutation (SNP) | VAF 215/517 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as rs121913294, CM074465, CM102472, COSV100911374, COSV64288961, COSV64302184; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTRT3 | c.48G>A p.M16I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV57754170, COSV57754887; called by muse, mutect2, varscan2
- ATM | c.7089+2T>A p.X2363_splice | Splice Site (SNP) | VAF 81/132 reads (61%) | catalogued as COSV99592054; called by muse, mutect2, varscan2
- BMX | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 84/122 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765370721, COSV59593893; called by muse, mutect2, varscan2
- C4BPA | c.1090T>G p.C364G | Missense Mutation (SNP) | VAF 161/559 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100891286; called by muse, mutect2, varscan2
- CCDC190 | c.221T>C p.L74S | Missense Mutation (SNP) | VAF 486/826 reads (59%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.571); catalogued as COSV100905846; called by muse, mutect2, varscan2
- DCSTAMP | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs566008351, COSV52576605; called by muse, mutect2, varscan2
- DDX20 | c.32T>A p.L11* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as rs903048222; called by muse, mutect2
- DENND5B | c.2906G>A p.G969E | Missense Mutation (SNP) | VAF 267/594 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV100172257; called by muse, mutect2, varscan2
- DRG2 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as COSV99234504; called by muse, mutect2, varscan2
- EXOC3L1 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs754761240, COSV99333971; called by muse, varscan2
- EYA4 | c.489T>A p.Y163* | Nonsense Mutation (SNP) | VAF 175/421 reads (42%) | catalogued as COSV100766386; called by muse, mutect2, varscan2
- FN1 | c.3922G>T p.E1308* | Nonsense Mutation (SNP) | VAF 91/275 reads (33%) | catalogued as COSV100118349; called by muse, mutect2, varscan2
- GPR158 | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 143/381 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs547187950, COSV66273277; called by muse, mutect2, varscan2
- HAUS6 | c.856A>G p.K286E | Missense Mutation (SNP) | VAF 126/316 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.158); catalogued as COSV100997914; called by muse, mutect2, varscan2
- HHIPL2 | c.1943C>T p.S648F | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as rs138250103; called by muse, mutect2, varscan2
- IFT80 | c.2042A>C p.Q681P | Missense Mutation (SNP) | VAF 203/537 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100425143; called by muse, mutect2, varscan2
- IL6R | c.206C>G p.S69C | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV100691147; called by muse, mutect2, varscan2
- OR4C13 | c.811G>C p.V271L | Missense Mutation (SNP) | VAF 210/485 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.181); catalogued as COSV101634245; called by muse, mutect2, varscan2
- OTOP2 | c.1291G>A p.G431R | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.061); catalogued as rs202152813, COSV100173078, COSV58881244; called by muse, mutect2, varscan2
- PDYN | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV54100904; called by muse, mutect2, varscan2
- PHF2 | c.703A>G p.K235E | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100823338; called by muse, mutect2, varscan2
- PRAMEF2 | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 198/485 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs755983436, COSV53580371; called by muse, mutect2, varscan2
- PTEN | c.104T>A p.M35K | Missense Mutation (SNP) | VAF 288/700 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as CM014083, CM981665, COSV100911372, COSV64292490; called by muse, mutect2, varscan2
- RFESD | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs780581345, COSV57224505, COSV99174189; called by muse, mutect2, varscan2
- SMARCE1 | c.511A>G p.M171V | Missense Mutation (SNP) | VAF 268/650 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99228505; called by muse, mutect2, varscan2
- TNS3 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.009); catalogued as rs779298838, COSV100236505; called by muse, mutect2, varscan2
- TSLP | c.427C>A p.Q143K | Missense Mutation (SNP) | VAF 124/319 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV100789223; called by muse, mutect2, varscan2
- WDR90 | c.1576G>A p.G526S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as COSV99554215; called by muse, varscan2
- ZFYVE26 | c.4A>G p.N2D | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.062); catalogued as COSV100720704; called by muse, mutect2, varscan2
- PCDHGB5 | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- PIK3R1 | c.973_974del p.N325Yfs*7 (on ENST00000521381 / NM_181523.3; = p.N55Yfs*7 on NM_181504.4) | Frame Shift Del (DEL) | VAF 197/559 reads (35%) | called by mutect2, pindel, varscan2
- PTEN | c.489_492+4del p.X163_splice | Splice Site (DEL) | VAF 83/221 reads (38%) | called by mutect2, pindel, varscan2
- RB1 | c.1726_1729del p.S576Rfs*34 | Frame Shift Del (DEL) | VAF 121/233 reads (52%) | called by mutect2, pindel, varscan2
- TRIR | c.484_510del p.A162_K170del | In Frame Del (DEL) | VAF 95/169 reads (56%) | called by mutect2, pindel, varscan2
- ZNF223 | c.1326_1327del p.Y442* | Nonsense Mutation (DEL) | VAF 138/378 reads (37%) | called by mutect2, pindel, varscan2
- CCDC27 | c.1059G>A p.T353= | Silent (SNP) | VAF 81/206 reads (39%) | catalogued as rs750596926, COSV99622956; called by muse, mutect2, varscan2
- GRPEL2 | c.87G>A p.P29= | Silent (SNP) | VAF 50/125 reads (40%) | catalogued as rs751066927, COSV100249851; called by muse, mutect2, varscan2
- MAGEL2 | c.2625C>T p.S875= | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as rs1204239959, COSV100046235; called by muse, mutect2, varscan2
- MTRR | c.279C>T p.P93= (on ENST00000264668; = p.P66= on NM_002454.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 32/304 reads (11%) | catalogued as rs776410065, COSV99241176, COSV99242127; ClinVar: likely benign; called by muse, mutect2, varscan2
- NRXN1 | c.2451T>A p.R817= | Silent (SNP) | VAF 111/288 reads (39%) | catalogued as rs1486110547, COSV100457004; called by muse, mutect2, varscan2
- PCDHGB3 | c.1869G>A p.T623= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV53937747; called by muse, varscan2
- PHACTR3 | c.990G>A p.T330= | Silent (SNP) | VAF 118/265 reads (45%) | catalogued as rs767852524, COSV63026366; called by muse, mutect2, varscan2
- SMG1 | c.10140C>T p.T3380= | Silent (SNP) | VAF 115/383 reads (30%) | catalogued as rs1290345649, COSV101246882; called by muse, mutect2, varscan2
- MFRP | chr11:119345552 C>T | 5'Flank (SNP) | VAF 48/63 reads (76%) | catalogued as COSV100793551; called by muse, mutect2, varscan2
